Somatic mutation profile of tumor specimen 0DKMGH from CCDI case PBBYIU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,260 days).
Specimen 0DKMGH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb68e44-b8b9-4c70-93d8-e3d0af13cf95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKMG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d38ef37-a9f5-4c1c-a272-6230b8622a13

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL22A1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 55/1414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225221507, COSV57336822; called by muse, mutect2
- ADAMTSL5 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2
- HYAL4 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 25/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MOSPD2 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ANKIB1 | c.-64C>T | 5'UTR (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
